Somatic mutation profile of tumor specimen ALCH-B1R1-TTP1-A (aliquot ALCH-B1R1-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1R1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,244 days).
Specimen ALCH-B1R1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b803bb0a-475c-40b1-982b-e7a909653c3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1R1-NB1-A (Blood Derived Normal), aliquot ALCH-B1R1-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/483cb6c8-d100-46d2-ba44-c53469e56a5a

The open-access MAF lists 222 somatic variants for this specimen: 149 protein-altering or splice-affecting, 49 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 49, Nonsense Mutation 15, Intron 11, Splice Site 8, 3'UTR 4, RNA 4, 5'UTR 2, 5'Flank 2, Frame Shift Del 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 31/219 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB5 | c.1940C>G p.P647R (on ENST00000404938 / NM_001163941.2; = p.P202R on NM_178559.6) | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV51722570; called by muse, mutect2
- ADAMTSL3 | c.2844G>T p.K948N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54441881; called by muse, mutect2, varscan2
- ADGRL2 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54677252; called by muse, mutect2
- ADH1C | c.18+2T>A p.X6_splice | Splice Site (SNP) | VAF 8/200 reads (4%) | catalogued as rs938157117, COSV72463527; called by muse, mutect2
- AHSG | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56607965; called by muse, mutect2, varscan2
- BCAS1 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65086187; called by muse, mutect2, varscan2
- CAPN1 | c.442A>C p.I148L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs753257635, COSV99658372; called by muse, mutect2, varscan2
- CCDC172 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs769720190; called by muse, mutect2, varscan2
- CDH22 | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs368116505; called by mutect2, varscan2
- CDH9 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50252202, COSV50339420, COSV50368967; called by muse, mutect2
- CDON | c.3560G>T p.R1187L | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV54999188; called by muse, mutect2
- CEP192 | c.4963-1G>T p.X1655_splice | Splice Site (SNP) | VAF 5/83 reads (6%) | catalogued as COSV58060847; called by muse, mutect2
- CNTNAP4 | c.3074G>T p.S1025I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100273338; called by muse, mutect2
- CUBN | c.6652G>T p.G2218W | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64727751; called by muse, mutect2
- DNAH5 | c.6860G>C p.R2287P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54257570; called by muse, mutect2, varscan2
- DNAH5 | c.6859C>T p.R2287W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs747326567, COSV54213059; called by muse, mutect2, varscan2
- EPHA3 | c.1698-1G>T p.X566_splice | Splice Site (SNP) | VAF 22/175 reads (13%) | catalogued as COSV60698561; called by muse, mutect2, varscan2
- EVL | c.460G>C p.E154Q (on ENST00000402714 / NM_001330221.2; = p.E156Q on NM_016337.3) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67374298, COSV67374616, COSV67375575; called by muse, mutect2
- EYA4 | c.1022C>A p.P341H (on ENST00000531901 / NM_001301013.1; = p.P335H on NM_004100.5) | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62057604; called by muse, mutect2
- GABRA1 | c.944G>T p.W315L | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.91); catalogued as rs747138999, COSV99195892; called by muse, mutect2
- GAREM1 | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV99331344; called by muse, mutect2, varscan2
- GPHN | c.1124G>T p.G375V (on ENST00000315266 / NM_001377519.1; = p.G408V on NM_020806.5) | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1513735; called by muse, mutect2
- GPM6A | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV99702483; called by muse, mutect2, varscan2
- IGLV3-21 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs1267055233; called by muse, mutect2, varscan2
- IRS4 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.153); catalogued as COSV100929541; called by muse, mutect2, varscan2
- MINDY4 | c.935A>T p.D312V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs758831576; called by muse, mutect2, varscan2
- MSR1 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 14/312 reads (4%) | catalogued as COSV100026865; called by muse, mutect2
- MYT1L | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV67729445; called by muse, mutect2
- NBEA | c.7297G>T p.E2433* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV59822183; called by muse, mutect2
- NCAPG2 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs1283653423; called by muse, mutect2
- NFATC1 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53710630; called by muse, mutect2, varscan2
- NTRK3 | c.2441G>T p.R814L (on ENST00000360948 / NM_001012338.2; = p.R800L on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62317020; called by muse, mutect2
- OR13F1 | c.913C>A p.L305M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as COSV58252435; called by muse, mutect2
- OR2T6 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as rs1450806102; called by muse, mutect2
- OR5L1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958685864, COSV100450120; called by mutect2, varscan2
- PANX3 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV52512774; called by muse, mutect2, varscan2
- PARD3B | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100595021; called by muse, mutect2, varscan2
- PCDH9 | c.2297C>A p.T766K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV60566939; called by muse, mutect2, varscan2
- PCDHA10 | c.1240C>A p.R414S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs782208845, COSV56532873; called by muse, mutect2, varscan2
- PHLPP2 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868413305; called by muse, mutect2
- PLEKHA4 | c.2327A>C p.Q776P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs763288404; called by muse, mutect2, varscan2
- RSPH1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52319434; called by muse, mutect2
- SBF1 | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as rs1556425608, COSV62370385; called by muse, varscan2
- SLCO3A1 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV59227564; called by muse, mutect2
- SPTLC3 | c.1415+1G>A p.X472_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as rs749941595, COSV100983322; called by mutect2, varscan2
- TAFA2 | c.164A>T p.K55M | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV69183241; called by muse, mutect2
- TMEM132B | c.3053G>A p.G1018D | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs754992744; called by muse, mutect2, varscan2
- TMEM45A | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100058282; called by muse, mutect2, varscan2
- TRPV5 | c.1327C>G p.R443G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV54688182; called by muse, mutect2
- TTN | c.19403C>A p.S6468* (on ENST00000591111; = p.S5541* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV60195448; called by muse, mutect2
- UGT2B15 | c.1458G>T p.W486C | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57732847, COSV57734888; called by muse, mutect2, varscan2
- USP6 | c.156-7C>A | Splice Region (SNP) | VAF 8/64 reads (13%) | catalogued as COSV51488079; called by muse, mutect2, varscan2
- VPS13B | c.7003G>T p.G2335W | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62142743; called by muse, mutect2
- ZNF416 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV52185246; called by muse, mutect2
- ZNF804A | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV56463989; called by muse, mutect2, varscan2
- ABCC2 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADA2 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- ADD2 | c.537A>T p.E179D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP12 | c.1478C>G p.P493R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- AMHR2 | c.1243C>A p.L415M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD13C | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- AP3B2 | c.3122C>A p.A1041E (on ENST00000261722; = p.A1035E on NM_004644.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- AP4B1 | c.746C>G p.P249R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.384); called by muse, mutect2
- ARID4B | c.3695G>T p.R1232L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ASB5 | c.235A>T p.S79C | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.139); called by muse, varscan2
- CATSPERB | c.932-1G>A p.X311_splice | Splice Site (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- CCT8L2 | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- CD244 | c.881G>A p.S294N (on ENST00000368033 / NM_001166663.2; = p.S289N on NM_016382.4) | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- CDH11 | c.2002G>A p.G668S | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH15 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CFH | c.2591G>T p.C864F | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNR1 | c.164del p.G55Efs*8 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- COBL | c.2244G>T p.R748S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2
- COL18A1 | c.2761G>T p.G921C (on ENST00000359759 / NM_130444.3; = p.G686C on NM_030582.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPS1 | c.4490G>C p.G1497A | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CR2 | c.2291G>T p.S764I | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- CRACD | c.2608A>T p.K870* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- CSMD3 | c.10354G>T p.V3452L (on ENST00000297405 / NM_001363185.1; = p.V3283L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2
- DICER1 | c.3151G>C p.A1051P | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DRD2 | c.799A>T p.R267W | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- EHMT1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ENPP3 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- FAM135B | c.3427G>C p.V1143L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM171A1 | c.304T>C p.W102R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASLG | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- FEZ2 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRY | c.1596A>T p.R532S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- GABRP | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- GAREM1 | c.1238G>A p.W413* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2
- GEMIN5 | c.2818G>T p.A940S | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.609); called by muse, mutect2
- HIVEP1 | c.1255_1259delinsC p.S419Rfs*3 | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | called by pindel, varscan2*
- IGHV4-61 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- IQGAP2 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- KANK4 | c.2884-2A>C p.X962_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- KIF5A | c.2735G>T p.R912L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KMO | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- KRTAP10-3 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- KRTAP9-1 | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- LAPTM5 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, varscan2
- LGR5 | c.1730T>C p.L577S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- LPA | c.2728G>T p.A910S | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- MARCHF1 | c.723C>A p.C241* (on ENST00000274056; = p.C224* on NM_017923.4) | Nonsense Mutation (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- MGAM2 | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MRC1 | c.3425C>A p.A1142E | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- MTA2 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NPHS2 | c.691C>A p.L231I | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- NRXN1 | c.3671C>A p.A1224D | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP98 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2
- OR2C3 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2
- OR5B21 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- PACSIN3 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PARP8 | c.1702G>C p.A568P | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCDH17 | c.3070G>T p.A1024S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PCDHGC3 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCLO | c.5753A>T p.Y1918F | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHEX | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.703); called by muse, varscan2
- PLCG2 | c.3339G>T p.W1113C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PLXNA2 | c.4144G>T p.D1382Y | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF8 | c.2178G>T p.W726C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR32 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RANBP2 | c.9034+1G>T p.X3012_splice | Splice Site (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- RGS9 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2
- RIMS2 | c.1153A>T p.M385L (on ENST00000666250 / NM_001348490.2; = p.M193L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.006); called by muse, mutect2
- RIOX2 | c.904A>T p.T302S (on ENST00000333396 / NM_001042533.2; = p.T301S on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF17 | c.4833G>A p.M1611I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2
- RPH3A | c.605C>A p.A202D (on ENST00000389385 / NM_001143854.2; = p.A198D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RXFP1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RXRG | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B1 | c.3695G>C p.G1232A | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- SH2B3 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SH3TC2 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.669); called by muse, mutect2
- SLC17A1 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- SMIM10 | c.193T>A p.F65I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- SYCE1 | c.907C>A p.P303T (on ENST00000343131 / NM_001143764.3; = p.P267T on NM_130784.3) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2
- TNFSF15 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- TNP1 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); called by muse, mutect2
- TRIM51GP | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TRIM58 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRPA1 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- TSNAX | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC3 | c.3939G>T p.L1313F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TUB | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- UGT1A4 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- USP10 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, varscan2
- ZKSCAN8 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ZNF469 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF518B | c.2590T>A p.L864M | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2
- ZNF527 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- AATF | c.549G>T p.G183= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- ACSS3 | c.942G>T p.G314= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- ADAM21 | c.1272C>A p.S424= | Silent (SNP) | VAF 16/249 reads (6%) | called by muse, mutect2
- ADAM21 | c.2103C>A p.V701= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- ASB17 | c.93C>A p.S31= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- ATP2B3 | c.3321C>A p.G1107= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- CDH11 | c.2001G>T p.G667= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV51750211; called by muse, mutect2
- CEMIP2 | c.3321G>A p.L1107= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- CSMD3 | c.7875T>A p.P2625= (on ENST00000297405 / NM_001363185.1; = p.P2521= on NM_052900.3) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV52174140; called by muse, mutect2, varscan2
- DNA2 | c.861G>A p.G287= | Silent (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- EGF | c.2640G>C p.V880= | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- ELAVL2 | c.576C>A p.P192= | Silent (SNP) | VAF 15/187 reads (8%) | catalogued as COSV56357156, COSV56366251; called by muse, mutect2
- ENOX2 | c.249G>A p.L83= (on ENST00000338144 / NM_001382520.1; = p.L54= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- EXOC4 | c.1629G>A p.E543= | Silent (SNP) | VAF 13/278 reads (5%) | catalogued as rs1422650316; called by muse, mutect2
- FAM135B | c.3843C>A p.T1281= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- FFAR3 | c.792C>A p.L264= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- FOXRED1 | c.36G>T p.R12= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- FSIP2 | c.17313T>A p.P5771= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100555739; called by muse, mutect2
- GOLGA2 | c.1746G>T p.L582= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- HADHB | c.306C>A p.I102= | Silent (SNP) | VAF 24/329 reads (7%) | catalogued as COSV58549171; called by muse, mutect2
- HUWE1 | c.5781C>G p.T1927= | Silent (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.184C>T p.L62= | Silent (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- IL13RA2 | c.786G>A p.L262= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV54564417; called by muse, mutect2, varscan2
- KIF1A | c.4344C>A p.P1448= (on ENST00000320389 / NM_001379639.1; = p.P1440= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- KRT33B | c.96C>A p.P32= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV52440000; called by muse, mutect2
- LCE2D | c.213C>T p.C71= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- LMNB2 | c.454C>T p.L152= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- LRRN3 | c.1674C>G p.V558= | Silent (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- MRGPRX2 | c.45G>T p.V15= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- NIPBL | c.4713A>T p.S1571= | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- NPHS1 | c.2406G>T p.R802= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- NUAK1 | c.600C>T p.S200= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs768498114; called by muse, mutect2, varscan2
- OR8S1 | c.546A>T p.P182= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- PCDH11X | c.3816C>A p.A1272= | Silent (SNP) | VAF 34/191 reads (18%) | catalogued as COSV100008048; called by muse, mutect2, varscan2
- PCDHA3 | c.420G>T p.L140= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV65371316; called by muse, mutect2
- PCDHA5 | c.1626G>T p.P542= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV65349020; called by muse, mutect2
- PDIA2 | c.1431A>G p.E477= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- PXDNL | c.3399G>T p.A1133= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- RASAL2 | c.192G>T p.T64= | Silent (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- RIMS2 | c.2611C>A p.R871= (on ENST00000666250 / NM_001348490.2; = p.R679= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- TAS1R2 | c.2100G>T p.T700= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- TENT5D | c.612T>A p.A204= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100382665; called by muse, mutect2
- TFAP2D | c.1254C>A p.G418= | Silent (SNP) | VAF 41/251 reads (16%) | catalogued as rs550127521, COSV99147090; called by muse, mutect2, varscan2
- ULK4 | c.2694A>G p.T898= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- UNC5D | c.2709C>T p.N903= | Silent (SNP) | VAF 20/260 reads (8%) | catalogued as COSV54811994; called by muse, mutect2
- USH2A | c.690G>T p.V230= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- VPS54 | c.228A>G p.A76= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as rs1255504575; called by muse, mutect2
- XCL2 | c.18G>C p.L6= | Silent (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- ZNF804A | c.2742C>A p.P914= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4547T>A | RNA (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- AC139792.3 | chr5:34124456 C>A | 5'Flank (SNP) | VAF 14/141 reads (10%) | catalogued as rs530509264; called by muse, mutect2
- ADGRE4P | n.1783C>G | RNA (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- AGAP14P | n.1766G>T | RNA (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- CHD8 | c.5051+506A>T | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- DLG3 | c.*36A>G | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ETDB | chrX:135123392 G>T | 5'Flank (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- FER1L4 | n.2669G>A | RNA (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- GTF3C4 | c.*13G>A | 3'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs762496559; called by muse, mutect2, varscan2
- IDH3B | c.*220C>T | 3'UTR (SNP) | VAF 9/93 reads (10%) | catalogued as rs747001383, COSV61389470; called by muse, mutect2, varscan2
- IRF2 | c.529+921G>T | Intron (SNP) | VAF 17/129 reads (13%) | catalogued as COSV66931129; called by muse, mutect2, varscan2
- MUCL3 | c.946+315A>G | Intron (SNP) | VAF 42/258 reads (16%) | called by muse, mutect2, varscan2
- NLGN4Y | c.473-3634A>G | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- PCOLCE2 | c.449-199C>A | Intron (SNP) | VAF 12/212 reads (6%) | catalogued as rs1211474022; called by muse, mutect2
- PLCE1 | c.1810-25G>T | Intron (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- REXO1L1P | chr8:85655117 A>T | 3'Flank (SNP) | VAF 10/258 reads (4%) | catalogued as rs1354203099; called by muse, mutect2
- USH2A | c.-23G>T | 5'UTR (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- VPS13C | c.10863+34G>T | Intron (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- Z82190.2 | c.1787-21861C>T | Intron (SNP) | VAF 12/87 reads (14%) | catalogued as rs1304391965; called by muse, mutect2, varscan2
- Z82190.2 | c.1787-21860A>T | Intron (SNP) | VAF 10/80 reads (13%) | called by muse, varscan2
- ZAN | c.7987-46C>A | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- ZFHX3 | c.-1007A>T | 5'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- ZNF195 | c.4-1889A>G | Intron (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- ZNF672 | c.*322C>T | 3'UTR (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2, varscan2
